Gene-level copy-number profile of tumor specimen TCGA-F4-6459-01A from TCGA case TCGA-F4-6459, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 61.8 years (22,574 days).
Specimen TCGA-F4-6459-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.fd50e954-a48b-4bb8-b939-edc949c47635.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F4-6459-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c47e837b-9a16-4fe7-9dc9-997c672146e4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 6; copy number 2: 1,917; copy number 3: 2,277; copy number 4: 31,067; copy number 5: 4,060; copy number 6: 8,663; copy number 7: 5,567; copy number 8: 2,418; copy number 9: 1,382; copy number 10: 2,097; copy number 11: 7; copy number 14: 20; copy number 18: 56; copy number 19: 69; copy number 23: 208.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F4-6459-01A-11D-1770-01): tumor purity 0.63, ploidy 2.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,839 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:188,508,538–189,037,564, 7 genes, copy number 11: AL929288.1, AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035, CLPTM1LP1.
- chr1:191,823,432–214,357,615, 468 genes, copy number 9–19 (broad region; genes not listed).
- chr3:69,739,464–71,754,229, 15 genes, copy number 9 (within-gene range 4–9): MITF, RN7SL418P, SAMMSON, AC139700.1, UQCRHP4, MDFIC2, AC104633.1, AC104633.2, COX6CP6, HMGB1P36, RNU6-281P, FOXP1, AC097634.4, FOXP1-AS1, MIR1284.
- chr3:85,385,710–85,385,792, 1 gene, copy number 9: MIR5688.
- chr6:62,547,427–63,779,336, 18 genes, copy number 14: AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,822,642, 2 genes, copy number 14: AL354719.1, SCAT8.
- chr7:70,972–40,099,580, 719 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr7:40,135,005–40,860,763, 1 gene, copy number 9 (within-gene range 4–9): SUGCT.
- chr7:40,538,127–62,275,678, 354 genes, copy number 9–10 (broad region; genes not listed).
- chr8:57,594,166–81,284,777, 353 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr8:81,440,326–81,461,579, 2 genes, copy number 10: PMP2, FABP9.
- chr8:93,646,066–95,811,254, 58 genes, copy number 9 (within-gene range 7–9): ZNF317P1, CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1, PDP1, MIR378D2HG, MIR378D2, PSMA2P2, RPL34P18, AC105081.1, AP003351.1, CDH17, AP003478.1, GEM, RPS4XP10, RAD54B, FSBP, VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1, INTS8, CCNE2, AC087752.4, AC087752.1, NDUFAF6, TP53INP1, AC087752.3, AC087752.2, AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1, MIR3150B, MIR3150A, PLEKHF2, C8orf37-AS1, LINC01298, C8orf37, AC024995.1, AC083836.1.
- chr13:18,467,172–28,778,937, 264 genes, copy number 18–23 (broad region; genes not listed).
- chr13:104,125,930–106,961,392, 28 genes, copy number 10: AL136524.1, RPL7P45, AL138954.1, DAOA-AS1, AL359751.2, AL359751.1, DAOA, AL359745.1, LINC00343, AL138701.1, AL138701.2, RNA5SP38, AL139379.1, LINC00460, RPL35P9, EFNB2, AL138689.2, AL138689.1, ARGLU1, LINC00551, LINC00443, ATP5MC1P5, AL163534.1, AL162574.2, PPIAP24, AL162574.1, AL162574.3, AL354741.1.
- chr13:107,788,342–110,990,579, 50 genes, copy number 9: FAM155A-IT1, AL359436.1, AL136964.1, LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, AL138694.1, HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, AL390755.3, COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20, AL139385.1, NAXD, CARS2, ING1, RPL21P107, LINC00567, PRECSIT, ANKRD10, ANKRD10-IT1, AL442128.2, PARP1P1, AL442128.1, LINC00431.
- chr13:112,647,044–113,154,002, 15 genes, copy number 9: ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2.
- chr16:69,424,619–90,222,851, 566 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr20:18,258,554–18,766,644, 24 genes, copy number 10 (within-gene range 7–10): RN7SL14P, RNU2-56P, AL049646.2, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851, DZANK1, GCNT1P1, RNA5SP476, POLR3F, MIR3192, RPL21P3, RBBP9, RPS19P1, SEC23B, SMIM26, AL121900.1, DTD1, RN7SL638P, RNU6ATAC34P, DUXAP7, DTD1-AS1.
- chr20:30,323,367–64,313,132, 894 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
